CCDI case PBBHWP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c7c3906b-34f9-4869-8d93-7f69fe27d3d4

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 13.4 years (4,912 days).

Biospecimens (3 samples)
- Sample 0D9CN2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9CNE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0D9CNQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
